Somatic mutation profile of tumor specimen TCGA-TM-A84C-01A (aliquot TCGA-TM-A84C-01A-11D-A36O-08) from TCGA case TCGA-TM-A84C, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Astrocytoma, NOS; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 32.4 years (11,849 days).
Specimen TCGA-TM-A84C-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8cf4ad6e-de1d-4e1a-8da9-7ebf8644c35d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-TM-A84C-12A (Buccal Cell Normal), aliquot TCGA-TM-A84C-12A-01D-A367-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1a615805-0368-4f77-acda-c44b6ec08cb4

The open-access MAF lists 16 somatic variants for this specimen: 14 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 12, Silent 2, Frame Shift Ins 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- H3-3A | c.83A>T p.K28M | Missense Mutation (SNP) | VAF 21/45 reads (47%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.697); catalogued as rs1057519903, COSV64731746, COSV64731769; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- NF1 | c.724dup p.M242Nfs*3 | Frame Shift Ins (INS) | VAF 16/83 reads (19%) | catalogued as rs1555608763, CI000104; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ADGRE2 | c.2309A>G p.Q770R | Missense Mutation (SNP) | VAF 8/152 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100215881; called by muse, mutect2
- INTS7 | c.2327G>A p.C776Y | Missense Mutation (SNP) | VAF 35/88 reads (40%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.994); catalogued as COSV100877454; called by muse, mutect2, varscan2
- JAG1 | c.2807G>A p.C936Y | Missense Mutation (SNP) | VAF 86/196 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1568792050, CM124884, COSV99652673; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KIF21B | c.2611C>G p.R871G | Missense Mutation (SNP) | VAF 30/77 reads (39%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.987); catalogued as COSV100144237; called by muse, mutect2, varscan2
- NF1 | c.6819G>A p.K2273= (on ENST00000358273 / NM_001042492.3; = p.K2252= on NM_000267.3) | Splice Region (SNP) | VAF 52/125 reads (42%) | catalogued as rs1060500373, COSV62193968; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- OR11L1 | c.373G>A p.A125T | Missense Mutation (SNP) | VAF 3/38 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100869407, COSV63313525; called by muse, mutect2
- PPM1D | c.1166A>G p.D389G | Missense Mutation (SNP) | VAF 32/93 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.395); catalogued as COSV100010770; called by muse, mutect2, varscan2
- PTPRJ | c.172A>G p.I58V | Missense Mutation (SNP) | VAF 42/93 reads (45%) | SIFT tolerated, low confidence (0.96); PolyPhen benign (0); catalogued as COSV101394808; called by muse, mutect2, varscan2
- SYNE1 | c.23434G>C p.E7812Q (on ENST00000367255 / NM_182961.4; = p.E7741Q on NM_033071.3) | Missense Mutation (SNP) | VAF 31/84 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99558939; called by muse, mutect2, varscan2
- TYRO3 | c.1898T>G p.I633S | Missense Mutation (SNP) | VAF 25/103 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.243); catalogued as COSV99777448; called by muse, mutect2, varscan2
- WDFY3 | c.6628A>G p.S2210G | Missense Mutation (SNP) | VAF 33/83 reads (40%) | SIFT tolerated (0.31); PolyPhen benign (0.277); catalogued as COSV99882913; called by muse, mutect2, varscan2
- ZNF606 | c.934A>T p.T312S | Missense Mutation (SNP) | VAF 33/80 reads (41%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.734); catalogued as COSV100357284; called by muse, mutect2, varscan2
- MTBP | c.672A>G p.V224= | Silent (SNP) | VAF 86/181 reads (48%) | catalogued as rs762700935, COSV100011986; called by muse, mutect2, varscan2
- PFKFB4 | c.9C>T p.S3= | Silent (SNP) | VAF 12/56 reads (21%) | catalogued as rs755616453, COSV99219504; called by muse, mutect2, varscan2
